FM case AD9567 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Basal Cell Neoplasms; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/57cc67e0-663d-4f8f-89ad-772626862636

Male, 49.9 years: Basal cell carcinoma, NOS (ICD-O-3 8090/3) of the skin; metastasis biopsied or resected from the other ill-defined sites. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
